Somatic mutation profile of tumor specimen C3L-04473-01 (aliquot CPT0238710007) from CPTAC case C3L-04473, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.2 years (24,550 days).
Specimen C3L-04473-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f1eadd5-caf8-4210-9258-74dc29d4a437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04473-31 (Blood Derived Normal), aliquot CPT0238750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f609c57-f3ea-423e-b5b2-3feb56e01d5d

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 36/612 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- BICDL2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 23/522 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs754296681; called by muse, mutect2
- CCDC168 | c.18458G>A p.R6153H | Missense Mutation (SNP) | VAF 25/460 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs952754355; called by muse, mutect2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 22/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2
- ITGA11 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 34/566 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs541103090, COSV59877131; called by muse, mutect2
- KLHL1 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 16/434 reads (4%) | catalogued as rs1206863431, COSV100917474, COSV64769679; called by muse, mutect2
- KMT2C | c.5386C>T p.Q1796* | Nonsense Mutation (SNP) | VAF 14/163 reads (9%) | catalogued as COSV51322431; called by muse, mutect2
- MKNK2 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 40/591 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs571058431, COSV51733053; called by muse, mutect2
- NAALAD2 | c.327C>A p.Y109* | Nonsense Mutation (SNP) | VAF 19/290 reads (7%) | catalogued as rs761742585; called by muse, mutect2
- SHANK1 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs771160741, COSV53260522; called by muse, mutect2
- TSHZ3 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs749005684; called by muse, mutect2
- BIN3 | c.636G>C p.M212I | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.258); called by muse, mutect2
- CCDC9 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 27/520 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- EIF3B | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- PSME4 | c.5195G>T p.C1732F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2
- SASH1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); called by muse, mutect2
- SLC16A2 | c.1337A>C p.Q446P | Missense Mutation (SNP) | VAF 21/643 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2
- SLIT3 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 42/663 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFAT | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 34/624 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.62); called by muse, mutect2
- ANKFN1 | c.1125C>T p.D375= | Silent (SNP) | VAF 31/357 reads (9%) | catalogued as rs759462310, COSV59459991, COSV59461321; called by muse, mutect2
- RYR1 | c.868C>T p.L290= | Silent (SNP) | VAF 63/763 reads (8%) | catalogued as rs756969591; called by muse, mutect2
- TRIM49 | c.339G>A p.L113= | Silent (SNP) | VAF 24/810 reads (3%) | catalogued as COSV100316191; called by muse, mutect2
- VCPIP1 | c.3429T>C p.V1143= | Silent (SNP) | VAF 23/377 reads (6%) | called by muse, mutect2
